FM case AD269 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/77a7203d-db75-4b50-b89b-171e2516219e

Male, 41.6 years: Adrenal cortical carcinoma (ICD-O-3 8370/3) of the adrenal gland; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
